Somatic mutation profile of tumor specimen TCGA-A5-A0R8-01A (aliquot TCGA-A5-A0R8-01A-11D-A10B-09) from TCGA case TCGA-A5-A0R8, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 81.5 years (29,777 days).
Specimen TCGA-A5-A0R8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7216bc4a-e610-453c-b0ea-70ab8c2c0e14.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A5-A0R8-10A (Blood Derived Normal), aliquot TCGA-A5-A0R8-10A-01D-A10B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/18efbcfd-9b5c-4f11-bfa4-14537d19dbd3

The open-access MAF lists 76 somatic variants for this specimen: 63 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 47, Silent 13, Nonsense Mutation 5, Frame Shift Del 4, Frame Shift Ins 3, Splice Site 2, In Frame Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 10/50 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, varscan2
- GNAO1 | c.607G>A p.G203R | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587777057, CM138673, COSV52613732; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.100C>G p.R34G | Missense Mutation (SNP) | VAF 22/113 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67960061, COSV67960966; called by muse, varscan2
- PTEN | c.219_222dup p.H75Kfs*4 | Frame Shift Ins (INS) | VAF 12/65 reads (18%) | catalogued as rs786204898; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.278A>G p.H93R | Missense Mutation (SNP) | VAF 27/118 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs121909238, CM051214, COSV100910602, COSV64296545, COSV64296755; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABR | c.2207G>A p.R736Q (on ENST00000302538 / NM_021962.5; = p.R699Q on NM_001092.5) | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.227); catalogued as rs200228390, COSV52144690; called by muse, mutect2, varscan2
- AC004593.2 | c.1112T>A p.I371K | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.94); PolyPhen benign (0.165); catalogued as COSV56091759; called by muse, mutect2, varscan2
- AFF4 | c.3232G>T p.A1078S | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.085); catalogued as COSV54794541; called by muse, mutect2, varscan2
- ANAPC2 | c.1490G>A p.R497H | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749339424, COSV60568920; called by muse, mutect2, varscan2
- ANKRD6 | c.1934C>T p.P645L (on ENST00000339746 / NM_001242809.2; = p.P640L on NM_014942.4) | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1374040266, COSV60231153; called by muse, mutect2, varscan2
- AR | c.1830A>T p.K610N | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV65956731; called by muse, varscan2
- ARID1A | c.3979C>T p.Q1327* | Nonsense Mutation (SNP) | VAF 12/51 reads (24%) | catalogued as rs1421112233, COSV61370791; called by muse, mutect2, varscan2
- CFHR5 | c.1430G>A p.R477H | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.941); catalogued as rs149905969; called by muse, varscan2
- CHD4 | c.2830C>T p.R944W (on ENST00000357008 / NM_001363606.2; = p.R957W on NM_001273.5) | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58896897; called by muse, mutect2, varscan2
- CTNNA3 | c.2047G>T p.V683L | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.584); catalogued as COSV65524319, COSV65530602; called by muse, mutect2, varscan2
- CTNND1 | c.1764T>A p.Y588* | Nonsense Mutation (SNP) | VAF 16/81 reads (20%) | catalogued as COSV62383398; called by muse, mutect2, varscan2
- DAPK1 | c.46G>C p.G16R | Missense Mutation (SNP) | VAF 37/161 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs759598995, COSV63787208; called by muse, mutect2, varscan2
- DCUN1D4 | c.620A>T p.K207M | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58122659; called by muse, mutect2, varscan2
- DEFB136 | c.56-1G>A p.X19_splice | Splice Site (SNP) | VAF 11/40 reads (28%) | catalogued as COSV66363877; called by muse, mutect2, varscan2
- DNAH11 | c.6565C>T p.R2189* | Nonsense Mutation (SNP) | VAF 17/80 reads (21%) | catalogued as rs778698443, COSV60954805; called by muse, mutect2, varscan2
- DTX4 | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0.009); catalogued as COSV57090469; called by muse, mutect2, varscan2
- FAM120C | c.2968C>G p.P990A | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.661); catalogued as COSV60259228; called by muse, mutect2, varscan2
- GALNT13 | c.1427G>A p.R476Q | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.91); catalogued as rs148805770; called by muse, mutect2, varscan2
- GAP43 | c.654G>T p.K218N | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.339); catalogued as COSV59344099; called by muse, mutect2, varscan2
- GFUS | c.431C>G p.S144W | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101437050, COSV71254268; called by muse, mutect2, varscan2
- GLG1 | c.3434A>G p.N1145S | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as rs1393254050, COSV52666759; called by muse, mutect2, varscan2
- GLP2R | c.872C>T p.P291L | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.055); catalogued as rs1189545350, COSV52324662; called by muse, mutect2, varscan2
- INSR | c.2767G>A p.V923M | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs760156961, COSV57162328; called by muse, mutect2, varscan2
- KMT2B | c.7117C>T p.P2373S | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV55860799; called by muse, mutect2
- LAMA1 | c.4652C>T p.T1551I | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.295); catalogued as rs1275577824, COSV67536606; called by muse, mutect2, varscan2
- LRRC4 | c.946C>T p.R316* | Nonsense Mutation (SNP) | VAF 8/33 reads (24%) | catalogued as COSV50813884, COSV50819864; called by muse, mutect2, varscan2
- MARS1 | c.741G>T p.L247F | Missense Mutation (SNP) | VAF 24/161 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV56254564; called by muse, mutect2, varscan2
- MBD1 | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53274452; called by muse, mutect2, varscan2
- MDN1 | c.13684T>G p.F4562V | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as COSV65521270; called by muse, mutect2, varscan2
- MPP7 | c.1407+1G>A p.X469_splice | Splice Site (SNP) | VAF 20/97 reads (21%) | catalogued as COSV61732188; called by muse, mutect2, varscan2
- MROH7 | c.3182C>T p.A1061V | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs201277023; called by muse, mutect2, varscan2
- MTMR10 | c.384A>T p.K128N | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as COSV58728138; called by muse, mutect2, varscan2
- MUC15 | c.808T>A p.S270T | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); catalogued as COSV55554290; called by muse, mutect2, varscan2
- MYO1H | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.844); catalogued as rs752321520, COSV60445517; called by muse, mutect2, varscan2
- NAV3 | c.3805G>A p.V1269M | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.94); PolyPhen benign (0.161); catalogued as COSV57078458; called by muse, mutect2, varscan2
- NCKAP5 | c.1231C>T p.R411* | Nonsense Mutation (SNP) | VAF 20/89 reads (22%) | catalogued as COSV58438645; called by muse, mutect2, varscan2
- NOL8 | c.124C>T p.R42W | Missense Mutation (SNP) | VAF 40/169 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778480356, COSV62635296; called by muse, mutect2, varscan2
- OR5T2 | c.170C>A p.T57K | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV57589082; called by muse, mutect2, varscan2
- PCDH9 | c.569T>A p.L190Q | Missense Mutation (SNP) | VAF 21/166 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60548164; called by muse, mutect2, varscan2
- PCDHGA7 | c.1753G>A p.G585S | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.976); catalogued as rs372721131, COSV53943664; called by muse, mutect2, varscan2
- PCGF3 | c.121T>A p.C41S | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62859284; called by muse, mutect2, varscan2
- PKNOX1 | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.75); catalogued as rs371041625; called by muse, mutect2, varscan2
- PPP1R13L | c.1788C>A p.S596R | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs1409941034, COSV62908454; called by muse, mutect2, varscan2
- RAD9A | c.707_708del p.L236Qfs*5 | Frame Shift Del (DEL) | VAF 35/134 reads (26%) | catalogued as COSV57236823; called by mutect2, pindel, varscan2
- SGK1 | c.1100_1102del p.K367del | In Frame Del (DEL) | VAF 50/190 reads (26%) | catalogued as rs1562235584; called by pindel, varscan2
- SLC38A1 | c.1106C>T p.P369L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67063468; called by muse, varscan2
- TCF4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 50/210 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as COSV61896130; called by muse, mutect2, varscan2
- TMEM245 | c.2318G>A p.G773E | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.622); catalogued as COSV65822630; called by muse, mutect2, varscan2
- TRPV2 | c.977G>A p.R326Q | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368529239; called by muse, mutect2, varscan2
- TTC21A | c.1437del p.I479Mfs*11 | Frame Shift Del (DEL) | VAF 22/99 reads (22%) | catalogued as COSV100087778, COSV57184901; called by mutect2, pindel, varscan2
- ZNF486 | c.896G>A p.C299Y | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as rs782521968, COSV58718951; called by muse, mutect2, varscan2
- ZWINT | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs767486151, COSV59185347; called by muse, mutect2
- ADH4 | c.229del p.S77Vfs*6 | Frame Shift Del (DEL) | VAF 5/22 reads (23%) | called by mutect2, pindel, varscan2
- DR1 | c.282_283dup p.K95Ifs*4 | Frame Shift Ins (INS) | VAF 43/185 reads (23%) | called by mutect2, pindel, varscan2
- IFRD1 | c.686_714del p.T229Sfs*21 | Frame Shift Del (DEL) | VAF 22/100 reads (22%) | called by mutect2, pindel
- MACF1 | c.6058dup p.T2020Nfs*3 | Frame Shift Ins (INS) | VAF 6/47 reads (13%) | called by pindel, varscan2
- MRC1 | c.3068C>T p.T1023M | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- RIMBP3 | c.2992C>A p.Q998K | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- CTNND2 | c.1911C>A p.G637= | Silent (SNP) | VAF 33/123 reads (27%) | catalogued as COSV58880718; called by muse, mutect2, varscan2
- GPR149 | c.915C>T p.S305= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV67666390; called by muse, mutect2
- GRIA1 | c.789G>A p.P263= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs763737637, COSV53601622; called by muse, mutect2, varscan2
- KCND2 | c.588C>T p.A196= | Silent (SNP) | VAF 22/85 reads (26%) | catalogued as rs1275147629, COSV100477495, COSV58579092; called by muse, mutect2, varscan2
- LPAR5 | c.222G>T p.S74= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV100320918, COSV61692452; called by muse, mutect2
- PCDHB16 | c.1218G>A p.E406= | Silent (SNP) | VAF 24/104 reads (23%) | catalogued as COSV53361955; called by muse, mutect2, varscan2
- SHROOM2 | c.4485G>A p.L1495= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV66606383; called by muse, mutect2, varscan2
- TDRD5 | c.2130A>G p.P710= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as COSV54242398; called by muse, mutect2, varscan2
- TLE1 | c.1938C>T p.R646= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs139363416; called by muse, varscan2
- TUBA8 | c.69C>T p.L23= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV57812924; called by mutect2, varscan2
- UBXN2B | c.861A>G p.V287= | Silent (SNP) | VAF 22/91 reads (24%) | catalogued as COSV68309003; called by muse, mutect2, varscan2
- ZIK1 | c.582C>A p.P194= | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as COSV56736351, COSV56737126; called by muse, mutect2, varscan2
- ZNF687 | c.315C>T p.D105= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as rs202243324; called by muse, mutect2, varscan2
